Somatic mutation profile of tumor specimen TCGA-69-8253-01A (aliquot TCGA-69-8253-01A-11D-2284-08) from TCGA case TCGA-69-8253, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 59.6 years (21,771 days).
Specimen TCGA-69-8253-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2df6bd0b-430b-4804-a673-9439102f66bd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-69-8253-10A (Blood Derived Normal), aliquot TCGA-69-8253-10A-01D-2284-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c3cc60c0-f902-4da8-b5fe-282004a710b0

The open-access MAF lists 170 somatic variants for this specimen: 121 protein-altering or splice-affecting, 43 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 108, Silent 43, Nonsense Mutation 7, Intron 3, 3'UTR 2, In Frame Del 2, Splice Site 1, Splice Region 1, RNA 1, Frame Shift Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 4/9 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AARD | c.71C>A p.A24E | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV100991865; called by muse, mutect2
- ACSL4 | c.1907G>T p.W636L (on ENST00000340800 / NM_022977.2; = p.W595L on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/121 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.291); catalogued as COSV100538451; called by muse, mutect2, varscan2
- ACSM5 | c.1479G>T p.E493D | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV100088714; called by muse, mutect2, varscan2
- ADAP2 | c.309C>A p.N103K | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.76); PolyPhen benign (0.026); catalogued as rs527402641, COSV100437216; called by muse, mutect2, varscan2
- ADCY2 | c.406C>G p.Q136E | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV100602483; called by muse, mutect2
- ALG5 | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99523588; called by muse, mutect2, varscan2
- ARAP2 | c.4297C>G p.L1433V | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs753754399, COSV100394411; called by muse, mutect2, varscan2
- ATM | c.1977G>T p.K659N | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as rs1060501565, COSV99589028; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BCAR3 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.349); catalogued as rs776858691, COSV99550600; called by muse, mutect2, varscan2
- BRMS1 | c.76G>T p.E26* | Nonsense Mutation (SNP) | VAF 31/82 reads (38%) | catalogued as COSV100240209; called by muse, mutect2, varscan2
- BTRC | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.031); catalogued as COSV100926532; called by muse, mutect2, varscan2
- C3 | c.2117C>T p.S706L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs949465349, COSV99836459; called by muse, mutect2
- CACNA1E | c.6146C>A p.S2049Y (on ENST00000367573 / NM_001205293.3; = p.S2006Y on NM_000721.4) | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV100702005; called by muse, mutect2, varscan2
- CD34 | c.944G>T p.R315L | Missense Mutation (SNP) | VAF 196/542 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100178101; called by muse, mutect2, varscan2
- CD84 | c.50C>T p.P17L | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs544642873, COSV60866805; called by muse, varscan2
- CDK5RAP2 | c.1330G>C p.E444Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); catalogued as COSV100575316; called by muse, mutect2, varscan2
- CDKL5 | c.1799G>C p.S600T | Missense Mutation (SNP) | VAF 64/286 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.411); catalogued as COSV101184231; called by muse, mutect2, varscan2
- CHL1 | c.1897G>A p.E633K (on ENST00000397491 / NM_001253387.1; = p.E649K on NM_006614.4) | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.9); PolyPhen benign (0.07); catalogued as COSV99850775; called by muse, mutect2, varscan2
- CHRDL1 | c.34T>A p.F12I (on ENST00000372045; = p.F18I on NM_145234.4) | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV99487950; called by muse, mutect2, varscan2
- CMYA5 | c.6308A>T p.E2103V | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.494); catalogued as COSV101483980; called by muse, mutect2, varscan2
- CNTNAP2 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs764014323, COSV62158735; called by muse, mutect2, varscan2
- COL19A1 | c.835C>G p.Q279E | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as COSV100505985; called by muse, mutect2, varscan2
- CUBN | c.5324G>T p.R1775L | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.743); catalogued as COSV100912421; called by muse, mutect2, varscan2
- DCLK3 | c.161G>C p.C54S | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs544641970, COSV101373944; called by muse, mutect2, varscan2
- DDX53 | c.362C>A p.S121* | Nonsense Mutation (SNP) | VAF 24/117 reads (21%) | catalogued as COSV100028860; called by muse, mutect2, varscan2
- DNAH8 | c.7618G>C p.E2540Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100544337, COSV59480528; called by muse, varscan2
- DNAJC10 | c.1192-1G>T p.X398_splice | Splice Site (SNP) | VAF 21/64 reads (33%) | catalogued as COSV51143507; called by muse, mutect2, varscan2
- DOCK3 | c.3349A>C p.I1117L | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); catalogued as COSV99810859; called by muse, mutect2, varscan2
- EPC2 | c.905T>G p.L302R | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.119); catalogued as COSV99309399; called by muse, mutect2
- FAT3 | c.2150C>T p.S717L | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); catalogued as COSV53101384, COSV99963353; called by muse, mutect2, varscan2
- FCRL2 | c.1012G>C p.D338H | Missense Mutation (SNP) | VAF 63/180 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV100829879, COSV63832432; called by muse, mutect2, varscan2
- FLI1 | c.1217C>T p.S406F | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.139); catalogued as COSV99857581; called by muse, mutect2, varscan2
- FTMT | c.596A>G p.N199S | Missense Mutation (SNP) | VAF 33/236 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.035); catalogued as COSV100360298; called by muse, mutect2, varscan2
- GABRR3 | c.1027C>G p.L343V | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV101512275; called by muse, mutect2, varscan2
- GPC6 | c.945A>G p.I315M | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100988423; called by muse, mutect2, varscan2
- HIF3A | c.1026C>A p.S342R (on ENST00000377670 / NM_152795.4; = p.S273R on NM_022462.4) | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV99039631; called by muse, mutect2, varscan2
- HSF5 | c.292G>T p.G98W | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.868); catalogued as COSV100050944; called by muse, mutect2, varscan2
- HTR1E | c.761C>T p.T254I | Missense Mutation (SNP) | VAF 52/249 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.14); catalogued as COSV100541040; called by muse, mutect2, varscan2
- IFIH1 | c.2576A>T p.H859L | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as COSV99718567; called by muse, mutect2
- IGLON5 | c.939G>C p.E313D | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.204); catalogued as COSV54534520, COSV99570586; called by muse, varscan2
- IQSEC3 | c.1132G>T p.G378W (on ENST00000538872 / NM_001170738.2; = p.G75W on NM_015232.1) | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100407048; called by muse, mutect2, varscan2
- IRS2 | c.761T>G p.F254C | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs746497031, COSV101018970; called by muse, mutect2
- ITGA3 | c.2443G>T p.V815F | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.76); PolyPhen benign (0.015); catalogued as COSV99143508; called by muse, mutect2, varscan2
- KCNK4 | c.871G>T p.G291W | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100107713; called by muse, mutect2, varscan2
- KEAP1 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 34/101 reads (34%) | catalogued as COSV99407622; called by muse, mutect2, varscan2
- KLK5 | c.320C>A p.A107D | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100306984; called by muse, mutect2, varscan2
- KMT2B | c.2174C>T p.P725L | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV99385983; called by muse, mutect2, varscan2
- LARS2 | c.1589A>G p.Y530C | Missense Mutation (SNP) | VAF 32/194 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as COSV55526333; called by muse, mutect2, varscan2
- MUC16 | c.6907A>C p.K2303Q | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as COSV101199345; called by muse, mutect2, varscan2
- MYC | c.437C>T p.S146L (on ENST00000377970; = p.S161L on NM_002467.6) | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV52367052; called by muse, mutect2, varscan2
- N4BP2L2 | c.2284C>A p.H762N (on ENST00000674422; = p.H333N on NM_033111.4) | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100678863; called by muse, mutect2
- NCOA3 | c.4184T>A p.M1395K (on ENST00000371998 / NM_181659.3; = p.M1391K on NM_006534.4) | Missense Mutation (SNP) | VAF 25/162 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV100507408; called by muse, mutect2, varscan2
- NEUROD6 | c.798C>A p.N266K | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.992); catalogued as COSV99773979; called by muse, mutect2, varscan2
- NLRP5 | c.2353C>T p.Q785* | Nonsense Mutation (SNP) | VAF 34/118 reads (29%) | catalogued as rs200446614, CM158625, COSV66767721; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NTRK2 | c.2233G>T p.E745* (on ENST00000323115 / NM_001369534.1; = p.E761* on NM_006180.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 48/203 reads (24%) | catalogued as COSV99454371; called by muse, mutect2, varscan2
- OR11H1 | c.764G>T p.C255F | Missense Mutation (SNP) | VAF 32/141 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99421728; called by mutect2, varscan2
- OR2G6 | c.946G>T p.D316Y | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100598094; called by muse, mutect2, varscan2
- OR2L8 | c.416T>A p.V139E | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV61727081; called by muse, mutect2, varscan2
- OR2T1 | c.539C>A p.A180E | Missense Mutation (SNP) | VAF 12/117 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV100822289; called by muse, mutect2, varscan2
- OR6K2 | c.47C>G p.A16G | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100656756, COSV62743152; called by muse, mutect2
- OSBP2 | c.1354T>C p.Y452H | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV100212923; called by muse, mutect2, varscan2
- PDZRN3 | c.1573A>T p.M525L | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.801); catalogued as COSV55213808, COSV99728841; called by muse, mutect2, varscan2
- PKDREJ | c.4990C>T p.R1664C | Missense Mutation (SNP) | VAF 20/50 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.332); catalogued as rs141791457; called by muse, mutect2, varscan2
- PKHD1 | c.9316A>T p.I3106F | Missense Mutation (SNP) | VAF 36/228 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs760012577, COSV100582455; called by muse, mutect2, varscan2
- PLB1 | c.3024C>G p.H1008Q | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.972); catalogued as COSV100578231; called by muse, mutect2, varscan2
- PLCB1 | c.1714G>T p.E572* | Nonsense Mutation (SNP) | VAF 30/80 reads (38%) | catalogued as COSV100570283; called by muse, mutect2, varscan2
- POU3F4 | c.58G>T p.A20S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100937199, COSV64537705, COSV64538282; called by muse, mutect2, varscan2
- PRDM9 | c.2422G>T p.E808* | Nonsense Mutation (SNP) | VAF 59/256 reads (23%) | catalogued as COSV99690230; called by muse, varscan2
- PRUNE2 | c.8734T>C p.Y2912H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99796000; called by muse, mutect2, varscan2
- PSG6 | c.305C>A p.S102Y | Missense Mutation (SNP) | VAF 121/488 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.21); catalogued as rs762668809, COSV99413865; called by muse, mutect2, varscan2
- PTPRCAP | c.557G>T p.S186I | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV57055496; called by muse, mutect2, varscan2
- RAG1 | c.2781C>G p.F927L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.983); catalogued as COSV100200817; called by muse, mutect2, varscan2
- REG3A | c.242G>T p.S81I | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100532639; called by muse, varscan2
- RFC1 | c.1667A>G p.K556R | Missense Mutation (SNP) | VAF 57/253 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100567572; called by muse, mutect2, varscan2
- RFX4 | c.2186C>A p.A729D (on ENST00000392842 / NM_213594.3; = p.A635D on NM_032491.6) | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as COSV99985685; called by muse, mutect2, varscan2
- RNF165 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as COSV99491520; called by muse, mutect2, varscan2
- RNF32 | c.967T>A p.S323T | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.271); catalogued as COSV100311352; called by muse, mutect2, varscan2
- RNF32 | c.1081G>C p.E361Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV58734889, COSV58734975; called by muse, mutect2, varscan2
- RPL22L1 | c.9G>A p.P3= | Splice Region (SNP) | VAF 7/53 reads (13%) | catalogued as rs985181044, COSV55557481, COSV99860582; called by muse, mutect2, varscan2
- RTTN | c.4853G>A p.C1618Y | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99731892; called by muse, mutect2, varscan2
- SAMD13 | c.143C>A p.P48H (on ENST00000370671; = p.P42H on NM_001010971.3) | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101043237, COSV65744666; called by muse, mutect2, varscan2
- SELE | c.488G>C p.C163S | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100324673; called by muse, mutect2, varscan2
- SGCA | c.1121G>T p.R374L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.06); catalogued as rs150524482, COSV100006655; called by mutect2, varscan2
- SGK2 | c.1124G>T p.G375V | Missense Mutation (SNP) | VAF 22/207 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100414606; called by muse, mutect2, varscan2
- SHROOM2 | c.3881G>T p.R1294L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.026); catalogued as COSV101098419; called by muse, mutect2, varscan2
- SLC25A34 | c.778C>T p.R260W | Missense Mutation (SNP) | VAF 11/102 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1050728352, COSV99606546; called by muse, mutect2, varscan2
- SNCAIP | c.1955C>A p.S652Y | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99748206; called by muse, mutect2, varscan2
- SNX9 | c.1313T>C p.I438T | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1256110267, COSV101093939; called by muse, mutect2, varscan2
- SPATA6 | c.1202G>A p.R401K | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.875); catalogued as rs369101569; called by muse, mutect2, varscan2
- SPTA1 | c.5041G>A p.V1681I | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs371655531; called by muse, mutect2, varscan2
- SS18L1 | c.648G>A p.M216I | Missense Mutation (SNP) | VAF 34/69 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.294); catalogued as rs748554878, COSV100064765; called by muse, mutect2, varscan2
- STAB1 | c.983G>T p.R328L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.039); catalogued as rs140679923, COSV100401525; called by muse, mutect2, varscan2
- STON1 | c.985A>T p.R329W | Missense Mutation (SNP) | VAF 31/143 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs753894249, COSV100561723; called by muse, mutect2, varscan2
- SYNPO2 | c.2024C>T p.S675L | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as COSV100205336; called by muse, mutect2, varscan2
- TAAR8 | c.459C>A p.S153R | Missense Mutation (SNP) | VAF 48/255 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.506); catalogued as COSV51585871, COSV99257172; called by muse, mutect2, varscan2
- TACC2 | c.4357G>C p.D1453H | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV100552072; called by muse, varscan2
- TACC2 | c.4714G>C p.E1572Q | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.829); catalogued as COSV100552074; called by muse, mutect2, varscan2
- TACR3 | c.624G>T p.W208C | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100510322; called by muse, mutect2, varscan2
- TMPPE | c.615C>A p.N205K | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.014); catalogued as COSV100257186; called by muse, mutect2
- TMX3 | c.376G>C p.A126P | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100218306; called by muse, mutect2, varscan2
- TOX4 | c.740A>T p.N247I | Missense Mutation (SNP) | VAF 81/218 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as COSV99398159; called by muse, mutect2, varscan2
- TTN | c.32674G>A p.V10892I (on ENST00000591111; = p.V9965I on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | PolyPhen benign (0.003); catalogued as rs1271411199, COSV100604993; called by muse, mutect2
- UGT2A2 | c.328C>A p.P110T | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.462); catalogued as COSV54140461, COSV99684146; called by muse, mutect2, varscan2
- USP53 | c.1444G>T p.D482Y | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.687); catalogued as COSV99917628; called by muse, mutect2, varscan2
- VRK2 | c.280C>G p.Q94E | Missense Mutation (SNP) | VAF 18/147 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV100417780; called by muse, mutect2, varscan2
- WDR7 | c.374G>T p.R125L | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.04); catalogued as COSV99589188; called by muse, mutect2, varscan2
- WNK3 | c.3010G>T p.V1004L | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV100671153; called by muse, mutect2, varscan2
- WWP1 | c.757G>T p.D253Y | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99616103; called by muse, mutect2, varscan2
- XIRP2 | c.8231A>T p.E2744V (on ENST00000628543; = p.E2919V on NM_152381.6) | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99741310; called by muse, mutect2
- ZC3H12B | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as rs777379401, COSV100161642; called by muse, mutect2
- ZIK1 | c.1061G>T p.G354V | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.11); catalogued as COSV100277430; called by muse, mutect2, varscan2
- ZNF761 | c.2190G>T p.K730N | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT tolerated (0.76); PolyPhen benign (0.037); catalogued as COSV100483334; called by muse, mutect2, varscan2
- ZNF804A | c.3554C>A p.P1185Q | Missense Mutation (SNP) | VAF 84/236 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV100167317, COSV56468377; called by muse, mutect2, varscan2
- OMG | c.29_31del p.L10_C11delinsR | In Frame Del (DEL) | VAF 27/96 reads (28%) | called by mutect2, pindel, varscan2
- SLC6A14 | c.660_665del p.V221_A222del | In Frame Del (DEL) | VAF 8/69 reads (12%) | called by mutect2, pindel, varscan2
- SNX15 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.145); called by muse, mutect2
- TAF1D | c.428del p.N143Tfs*8 | Frame Shift Del (DEL) | VAF 25/106 reads (24%) | called by mutect2, pindel, varscan2
- TAF1D | c.427A>G p.N143D | Missense Mutation (SNP) | VAF 26/101 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.014); called by mutect2, varscan2
- TNFRSF8 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TRAV9-2 | c.13C>A p.P5T | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ABCF1 | c.828A>T p.A276= (on ENST00000326195 / NM_001025091.2; = p.A238= on NM_001090.3) | Silent (SNP) | VAF 11/94 reads (12%) | catalogued as COSV100400791; called by muse, mutect2, varscan2
- AMY2B | c.1434A>T p.T478= | Silent (SNP) | VAF 102/354 reads (29%) | catalogued as COSV100796264; called by muse, mutect2, varscan2
- ARMCX3 | c.57C>T p.G19= | Silent (SNP) | VAF 25/88 reads (28%) | catalogued as rs372310822, COSV57871105; called by muse, mutect2, varscan2
- C5 | c.4779G>A p.E1593= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV99797615; called by muse, mutect2, varscan2
- CDH10 | c.396T>A p.I132= | Silent (SNP) | VAF 41/149 reads (28%) | catalogued as COSV100050950; called by muse, mutect2, varscan2
- CDH15 | c.2208C>T p.I736= | Silent (SNP) | VAF 10/17 reads (59%) | catalogued as rs774128146, COSV99228252; called by muse, varscan2
- CEACAM18 | c.781C>T p.L261= | Silent (SNP) | VAF 66/230 reads (29%) | catalogued as COSV101140293; called by muse, mutect2, varscan2
- CFAP100 | c.1485C>T p.T495= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV100729161; called by muse, mutect2, varscan2
- COL19A1 | c.99A>T p.S33= | Silent (SNP) | VAF 5/35 reads (14%) | catalogued as COSV100505984, COSV100507490; called by muse, mutect2, varscan2
- CYP4F22 | c.933G>T p.L311= | Silent (SNP) | VAF 15/86 reads (17%) | catalogued as COSV99512704; called by muse, mutect2, varscan2
- DMD | c.9528T>C p.D3176= | Silent (SNP) | VAF 24/127 reads (19%) | catalogued as COSV100626727; called by muse, mutect2, varscan2
- DPP10 | c.909T>A p.T303= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV100062355; called by muse, mutect2, varscan2
- EOMES | c.1344C>T p.N448= | Silent (SNP) | VAF 18/89 reads (20%) | catalogued as rs777301986, COSV55412430, COSV99841858; called by muse, mutect2, varscan2
- EPHA8 | c.1956G>C p.G652= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV99384603; called by muse, mutect2, varscan2
- FAIM2 | c.519C>A p.T173= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as COSV100277490; called by muse, mutect2, varscan2
- FGR | c.294C>T p.F98= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as COSV100925798; called by muse, mutect2, varscan2
- FSHR | c.543G>T p.G181= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV100436914; called by muse, mutect2, varscan2
- GLRA2 | c.1242G>T p.R414= | Silent (SNP) | VAF 28/140 reads (20%) | catalogued as COSV99490711; called by muse, mutect2, varscan2
- GPR158 | c.3024T>A p.P1008= | Silent (SNP) | VAF 19/80 reads (24%) | catalogued as COSV100893234; called by muse, mutect2, varscan2
- GPR25 | c.885G>C p.L295= | Silent (SNP) | VAF 34/89 reads (38%) | catalogued as COSV100421717, COSV58497853; called by muse, mutect2, varscan2
- KIFAP3 | c.1377A>T p.V459= | Silent (SNP) | VAF 27/77 reads (35%) | catalogued as COSV100846861, COSV63032675; called by muse, mutect2, varscan2
- MKRN3 | c.441G>A p.A147= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as rs757192830, COSV58811870; called by muse, mutect2, varscan2
- MRPS26 | c.315G>T p.L105= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV99848629; called by muse, mutect2, varscan2
- MUC16 | c.4368C>T p.P1456= | Silent (SNP) | VAF 39/103 reads (38%) | catalogued as rs1313360843, COSV67458740; called by muse, mutect2, varscan2
- MYH1 | c.2079C>A p.V693= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV56857246, COSV99875535; called by muse, mutect2, varscan2
- NDRG1 | c.489C>T p.I163= | Silent (SNP) | VAF 18/47 reads (38%) | catalogued as COSV100105867; called by muse, mutect2, varscan2
- OR6F1 | c.345G>T p.L115= | Silent (SNP) | VAF 20/78 reads (26%) | catalogued as COSV100129093; called by muse, mutect2, varscan2
- PCDH11X | c.1410C>T p.F470= | Silent (SNP) | VAF 17/103 reads (17%) | catalogued as rs768670963, COSV100007108; called by muse, mutect2, varscan2
- PCDHB3 | c.2133G>T p.V711= | Silent (SNP) | VAF 86/337 reads (26%) | catalogued as COSV99164841; called by muse, mutect2, varscan2
- PGM2L1 | c.1353G>A p.V451= | Silent (SNP) | VAF 44/139 reads (32%) | catalogued as COSV99994770; called by muse, mutect2, varscan2
- PRSS55 | c.57T>G p.G19= | Silent (SNP) | VAF 14/59 reads (24%) | catalogued as COSV100153727; called by muse, mutect2, varscan2
- SALL1 | c.3393C>T p.P1131= | Silent (SNP) | VAF 21/51 reads (41%) | catalogued as COSV99173153; called by muse, mutect2, varscan2
- SAMD14 | c.192G>T p.S64= | Silent (SNP) | VAF 23/123 reads (19%) | catalogued as rs538760933, COSV53309145, COSV99557404; called by muse, mutect2, varscan2
- SERPINA7 | c.1155C>A p.I385= | Silent (SNP) | VAF 51/318 reads (16%) | catalogued as COSV100568267, COSV59665248; called by muse, mutect2, varscan2
- SIX3 | c.306G>T p.T102= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as COSV99578219, COSV99578251; called by muse, mutect2, varscan2
- SLC2A6 | c.975C>T p.S325= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs372931255; called by muse, mutect2, varscan2
- SNX18 | c.909G>T p.T303= | Silent (SNP) | VAF 18/76 reads (24%) | catalogued as COSV100410358, COSV57989357; called by muse, mutect2, varscan2
- TACC2 | c.4911G>A p.Q1637= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as COSV100552077; called by muse, mutect2, varscan2
- TGIF2LX | c.597C>A p.S199= | Silent (SNP) | VAF 12/56 reads (21%) | catalogued as COSV99383269; called by muse, mutect2, varscan2
- TSHZ3 | c.2022G>A p.P674= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as rs151270303; called by muse, mutect2, varscan2
- USP36 | c.1110C>T p.V370= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100361407; called by muse, mutect2, varscan2
- ZFHX4 | c.546T>A p.S182= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV99261146; called by muse, mutect2, varscan2
- ZNF197 | c.966G>A p.K322= | Silent (SNP) | VAF 4/51 reads (8%) | catalogued as COSV60360727, COSV60360822; called by muse, mutect2
- DST | c.4297-2554C>A | Intron (SNP) | VAF 7/32 reads (22%) | catalogued as COSV99754141; called by muse, mutect2, varscan2
- MC5R | c.*1G>T | 3'UTR (SNP) | VAF 13/67 reads (19%) | catalogued as COSV100228997, COSV100229092; called by muse, mutect2, varscan2
- POLA1 | c.2947-21201G>T | Intron (SNP) | VAF 53/345 reads (15%) | called by muse, mutect2, varscan2
- SLC45A4 | c.*123G>T | 3'UTR (SNP) | VAF 16/87 reads (18%) | catalogued as COSV99196805; called by muse, mutect2, varscan2
- SSPOP | n.13690C>A | RNA (SNP) | VAF 22/105 reads (21%) | catalogued as COSV100947248; called by muse, mutect2, varscan2
- TCF3 | c.1823-425G>T | Intron (SNP) | VAF 10/46 reads (22%) | catalogued as rs372813564; called by muse, mutect2, varscan2
